Gene-level copy-number profile of tumor specimen TCGA-LN-A7HY-01A from TCGA case TCGA-LN-A7HY, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.1 years (18,296 days).
Specimen TCGA-LN-A7HY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.2e4ef47f-986a-4243-a5fb-b6eee32dac3d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A7HY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b9c9ed5-f84b-4dcf-a3c0-d4579d9c490a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 2,378; copy number 2: 18,397; copy number 3: 23,205; copy number 4: 10,467; copy number 5: 2,170; copy number 6: 1,336; copy number 7: 835; copy number 8: 572; copy number 9: 201; copy number 10: 112; copy number 13: 2; copy number 14: 13; copy number 18: 11; copy number 20: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A7HY-01A-12D-A350-01): tumor purity 0.53, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,321,663–246,322,438, 1 gene: SMYD3-IT1.
- chr1:248,810,446–248,919,946, 7 genes: SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr2:212,581,357–213,152,427, 8 genes (within-gene range 0–1): AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2.
- chr2:235,882,362–236,037,311, 2 genes: TMSB10P1, RNU7-127P.
- chr3:54,122,547–55,074,557, 5 genes (within-gene range 0–2): CACNA2D3, RPS15P5, ESRG, CACNA2D3-AS1, LRTM1.
- chr3:195,068,284–195,271,159, 1 gene (within-gene range 0–3): XXYLT1.
- chr3:195,134,506–195,263,628, 5 genes: MIR3137, RN7SL36P, XXYLT1-AS2, RNU6-25P, AC090018.2.
- chr3:195,280,723–195,282,741, 1 gene: ACAP2-IT1.
- chr5:94,111,720–94,618,597, 2 genes (within-gene range 0–1): AC117528.1, KIAA0825.
- chr5:97,504,663–97,738,913, 3 genes: LINC01340, MTCYBP40, AC112203.1.
- chr9:659,986–660,326, 1 gene: EIF1P1.
- chr9:5,629,025–6,008,482, 6 genes (within-gene range 0–2): RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA.
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–2): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:94,900,429–94,965,624, 3 genes: AL807757.2, AL353768.1, AL353768.2.
- chr10:74,344,550–74,424,014, 3 genes: TIMM9P1, RPSAP6, RAB5CP1.
- chr11:6,713,536–7,020,346, 14 genes (within-gene range 0–2): GVINP1, GVINP2, OR2AG2, OR2AG1, OR6A2, AC087280.2, AC087280.1, OR10A5, OR10A2, OR10A4, OR2D2, OR2D3, ZNF215, ZNF214.
- chr13:100,198,187–100,198,469, 1 gene: AL356575.1.
- chr17:16,084,042–16,098,807, 2 genes: RPL22P21, RNU6-314P.
- chr17:72,627,231–72,644,490, 2 genes: RPL32P33, AC080037.2.
- chr17:72,663,823–72,664,152, 1 gene: RN7SKP180.
- chr18:23,709,825–23,710,287, 1 gene: RPL23AP77.
- chr18:23,992,773–24,135,610, 1 gene (within-gene range 0–2): TTC39C.
- chr18:24,076,794–24,162,211, 6 genes: AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3.
- chr18:24,170,505–24,170,623, 1 gene: RNA5SP452.
- chr20:13,368,291–13,368,703, 1 gene: AL121782.1.
- chr20:13,392,677–13,393,674, 1 gene: GAPDHP2.
- chr21:25,880,550–26,171,128, 1 gene (within-gene range 0–2): APP.
- chr21:25,943,044–25,943,145, 1 gene: RNU6-123P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,761 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,754,216–42,424,232, 112 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:198,523,222–203,508,949, 135 genes, copy number 7 (broad region; genes not listed).
- chr3:141,918,252–170,181,749, 417 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr4:19,098,199–19,456,994, 4 genes, copy number 8: AC006840.1, LINC02438, RNA5SP157, AC024595.1.
- chr4:48,066,393–48,269,838, 5 genes, copy number 7 (within-gene range 4–7): TXK, RNU6-838P, U6, TEC, Y_RNA.
- chr4:173,924,207–189,002,075, 212 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr5:58,198–9,045,940, 186 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr5:9,546,200–23,689,386, 191 genes, copy number 8 (broad region; genes not listed).
- chr5:23,972,188–23,994,603, 3 genes, copy number 8: AC026784.1, ADH5P5, Y_RNA.
- chr5:50,396,192–50,934,521, 8 genes, copy number 7–8: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2.
- chr7:54,330,670–55,260,256, 17 genes, copy number 13–20: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr8:150,584–738,106, 19 genes, copy number 8: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1.
- chr8:738,548–740,374, 1 gene, copy number 8: AC100797.4.
- chr9:24,542,952–24,592,104, 2 genes, copy number 8: IZUMO3, AL353811.1.
- chr9:27,829,276–31,645,160, 28 genes, copy number 7–8: AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr11:33,665,220–35,420,063, 37 genes, copy number 8–14 (within-gene range 6–14): AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1.
- chr11:35,618,460–39,261,213, 35 genes, copy number 8–18: FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1, AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P.
- chr11:45,486,867–45,883,248, 13 genes, copy number 7: AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2.
- chr11:120,511,746–126,355,587, 180 genes, copy number 7 (broad region; genes not listed).
- chr11:128,836,315–135,075,908, 98 genes, copy number 7 (broad region; genes not listed).
- chr19:58,059,239–58,086,310, 1 gene, copy number 8 (within-gene range 4–8): ZNF135.
- chr19:58,083,838–58,605,223, 57 genes, copy number 8: ZSCAN18, ZNF329, AC008751.1, AC008751.3, AC008751.2, ZNF274, RPS15AP36, AC020915.3, ZNF544, AC020915.4, AC020915.2, AC020915.1, ZNF8, ZNF8-ERVK3-1, ERVK3-1, AC010642.2, AC010642.1, ZSCAN22, MIR6806, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1.

Autosomal genes at a single copy (total copy number 1): 2,377. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
